Surgical pathology report (de-identified scan), TCGA case TCGA-D9-A148, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D9-A148-06A (Metastatic).

11/22/10

Re

Site: lymph nodes, Nos
C77.9

page 1 / 1

Department of (

copy No. 1

Date:

Examination: Histopathological examination

Patient: [REDACTED]

PESEL:

Age:

Gender: **M**

Examination No.:

Material: Total organ resection – axillary lymph nodes

Unit in charge:

Physician in charge:

Material collected on: .

Material received on:

Expected time of examination: **up to 8 working days**

Clinical diagnosis:

Examination performed on: _____

Macroscopic description:

Surgical segment sized 15 x 12 x 8 cm with the lymph nodes, the largest one sized 12 x 6 x 5 cm.

Examination result:

Metastases melanomatis maligni in lymphonodis NO VI/XXV.

Infiltratio neoplastomaticae capsulae lymphonodos et telae adiposae perinodalis.

METASTASIS OF MALIGNANT MELANOMA IN LYMPH NOSES (VI / XXV).
NEOPLASMATIC INFILTRATION OF THE LYMPH NOSE CAPSULE AND ADJACENT
ADIPOSE TISSUE

Compliance validated by:

Major Malignancy History		X

Source: NCI Genomic Data Commons file 3055ba7e-d3e7-44f7-9405-026d7f99953d (TCGA-D9-A148.5361D1E9-BC8D-44F6-BE42-63AA2DE70982.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).